Somatic mutation profile of tumor specimen MP2PRT-PAVCAW-TMP1-A (aliquot MP2PRT-PAVCAW-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVCAW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,247 days).
Specimen MP2PRT-PAVCAW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd915aee-5e9a-49b9-8b8b-908ad0ab5d89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVCAW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVCAW-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6658e1e3-3391-401a-9d90-5b80b4a29edb

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 39/298 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CBLL1 | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 125/301 reads (42%) | catalogued as COSV56030442; called by muse, mutect2, varscan2
- KDM3B | c.4190G>A p.S1397N | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV58690234; called by muse, mutect2, varscan2
- KIR3DL1 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 83/96 reads (86%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs1350502368; called by muse, mutect2, varscan2
- KLK2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs142858357; called by muse, mutect2, varscan2
- LPIN1 | c.1426C>G p.R476G | Missense Mutation (SNP) | VAF 159/330 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs760960301; called by muse, mutect2, varscan2
- RECK | c.406-1G>A p.X136_splice | Splice Site (SNP) | VAF 74/202 reads (37%) | catalogued as COSV65036315; called by muse, mutect2, varscan2
- ADGRF3 | c.3170G>T p.C1057F | Missense Mutation (SNP) | VAF 139/342 reads (41%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD62 | c.1692G>A p.M564I | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HERC2 | c.9697G>A p.D3233N | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- IGKV2D-24 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MID1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 147/289 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PYGL | c.825C>T p.N275= | Silent (SNP) | VAF 31/248 reads (13%) | catalogued as rs1302019062; called by muse, mutect2, varscan2
- SYNE1 | c.9927G>A p.P3309= (on ENST00000367255 / NM_182961.4; = p.P3316= on NM_033071.3) | Silent (SNP) | VAF 169/375 reads (45%) | catalogued as rs140830584; called by muse, mutect2, varscan2
- TACC2 | c.3306C>T p.C1102= | Silent (SNP) | VAF 85/400 reads (21%) | catalogued as COSV57776642; called by muse, mutect2, varscan2
